Somatic mutation profile of tumor specimen MMRF_1348_1_BM_CD138pos (aliquot MMRF_1348_1_BM_CD138pos_T1_KAS5U_L01235) from MMRF case MMRF_1348, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,126 days).
Specimen MMRF_1348_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13a6cf0c-6744-4340-a29e-dd6d9e5a588d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1348_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1348_1_PB_Whole_C2_KAS5U_L01234; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5240a933-29bc-41c6-996c-a5c8376df3a3

The open-access MAF lists 74 somatic variants for this specimen: 32 protein-altering or splice-affecting, 3 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 24, Intron 8, 5'UTR 4, Silent 3, 5'Flank 2, Splice Region 2, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10 | c.1114C>T p.R372C (on ENST00000398564; = p.R347C on NM_014629.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs937444404; called by muse, mutect2
- DIP2B | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1201401269, COSV99998330; called by muse, mutect2, varscan2
- DMBT1 | c.7357G>A p.V2453M (on ENST00000338354 / NM_001377530.1; = p.V1696M on NM_004406.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs372434439; called by muse, mutect2, varscan2
- FCRLA | c.64T>C p.C22R (on ENST00000367959; = p.C5R on NM_032738.4) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as rs781249492; called by muse, mutect2, varscan2
- HGFAC | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs909661216; called by muse, mutect2, varscan2
- IGKJ3 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as rs368685523; called by muse, varscan2
- IGKV4-1 | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs374920058; called by muse, varscan2
- IGKV4-1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs749276071; called by muse, mutect2, varscan2
- KCNE4 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs779433664, COSV99918998; called by muse, mutect2, varscan2
- KRT26 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778623364; called by muse, mutect2, varscan2
- KRT84 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.347); catalogued as rs768390760; called by muse, mutect2, varscan2
- LRRC24 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs900044479; called by muse, mutect2
- OGA | c.2104T>C p.F702L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV63382179; called by muse, mutect2, varscan2
- PHF21B | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.766); catalogued as rs747226328, COSV57560640; called by muse, mutect2, varscan2
- PXDN | c.2117A>T p.N706I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53236952; called by muse, mutect2, varscan2
- TECRL | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1409531996, COSV101169360; called by muse, mutect2
- USP43 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs183408686; called by muse, mutect2, varscan2
- ZAN | c.5637C>T p.V1879= | Splice Region (SNP) | VAF 34/77 reads (44%) | catalogued as rs758085729; called by muse, mutect2, varscan2
- CNTN5 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); called by muse, mutect2
- CYP4F3 | c.397+3G>A | Splice Region (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV4-1 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, varscan2
- LY9 | c.1652A>T p.E551V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PRPF4B | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCD1 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINA4 | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX49 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- TPBG | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRMT1 | c.1739_1740insGTCCCC p.R580_R581insSP | In Frame Ins (INS) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- UNC79 | c.1870A>T p.I624F (on ENST00000393151 / NM_001346218.2; = p.I447F on NM_020818.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK2 | c.2362C>T p.L788F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ZNF717 | c.1515A>C p.K505N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYBL1 | c.1362A>C p.R454= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- PRRC2C | c.8235A>G p.Q2745= (on ENST00000367742; = p.Q2743= on NM_015172.4) | Silent (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- SLC13A3 | c.1479G>A p.P493= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs1205606883; called by muse, mutect2, varscan2
- AFDN | c.4947+869_4947+872del | Intron (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- BCL2L11 | c.*457T>C | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- C1QL1 | c.*277T>G | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- COL4A2 | c.*358C>T | 3'UTR (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- DNMT3B | c.-6-300G>A | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as rs1176673108; called by muse, mutect2
- EXOC5 | c.*2245A>C | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- F5 | chr1:169586492 del GGCTGTGG | 5'Flank (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- FJX1 | c.-172C>G | 5'UTR (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- GCNT1 | c.*3693A>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- GPR149 | c.*59A>T | 3'UTR (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- HEMK1 | c.*4315A>T | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- HMGCLL1 | c.*370T>C | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- IGLL5 | c.-156G>A | 5'UTR (SNP) | VAF 28/46 reads (61%) | catalogued as rs192654179, COSV73251062; called by muse, mutect2, varscan2
- IPO9 | c.*6625A>C | 3'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- KCTD20 | c.*1208A>G | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- KIF3C | c.*1198del | 3'UTR (DEL) | VAF 15/52 reads (29%) | catalogued as rs200769338; called by mutect2, varscan2
- LRIG3 | c.236+483A>G | Intron (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- LTBR | c.802-76G>T | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- MAN1A2 | c.*2833G>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851324 C>T | 5'Flank (SNP) | VAF 35/44 reads (80%) | catalogued as rs572738324; called by muse, mutect2, varscan2
- MLC1 | c.*757C>T | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- NGB | c.*435C>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- NKX3-2 | c.*214T>C | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- NR2F2 | c.*282T>C | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- PNRC1 | c.-64C>T | 5'UTR (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- QKI | c.934+1060T>C | Intron (SNP) | VAF 15/104 reads (14%) | catalogued as rs1562550350; called by muse, mutect2, varscan2
- RIMS3 | chr1:40623061 G>A | 3'Flank (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- ROBO2 | c.-371C>G | 5'UTR (SNP) | VAF 16/42 reads (38%) | catalogued as rs1237407358; called by muse, mutect2, varscan2
- RPS6KA2 | c.*1702A>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- SEL1L | c.*2136_*2138del | 3'UTR (DEL) | VAF 10/62 reads (16%) | catalogued as rs1566967560; called by pindel, varscan2
- SERPINA3 | c.644-257C>G | Intron (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- SFRP1 | c.*72C>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs980097227; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*4993A>G | 3'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs949368348; called by mutect2, varscan2
- STK16 | c.657+153G>C | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1095C>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99307596; called by muse, mutect2, varscan2
- VGLL3 | c.*654T>A | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- ZNF638 | c.-202-163A>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- ZNF662 | c.*1399dup | 3'UTR (INS) | VAF 18/47 reads (38%) | catalogued as rs1439289129; called by mutect2, varscan2
- ZRANB2 | c.*1202T>G | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
